Surgical pathology report (de-identified scan), TCGA case TCGA-33-4532, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4532-01A (Primary Tumor).

F. AL DIAGNOSIS ----- Pathologist: [REDACTED]

1. RIGHT LOWER LOBE, LUNG (RESECTION): MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (4.5 CM). THE TUMOR EXTENDS SUBPLEURALLY BUT DOES NOT INVADE THROUGH THE VISCERAL PLEURA. THE VASCULAR AND BRONCHIAL SURGICAL MARGINS ARE NEGATIVE FOR TUMOR. THREE (3) LYMPH NODES, NEGATIVE FOR TUMOR. THE PATHOLOGIC STAGE IS T2N0MX.

NOTE: Although we favor that this tumor represents a primary lung carcinoma, we cannot exclude the possibility of a lung metastasis on morphologic grounds.

2. STATION 7 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

3. R4 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file a68a3739-aadb-405e-bb48-79c9282f0886 (TCGA-33-4532.6EC80633-F41F-4A9D-ABFE-B1C72F9F9D10.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).